FM case AD5941 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Cystic, Mucinous and Serous Neoplasms; Primary site: Retroperitoneum and peritoneum.
https://portal.gdc.cancer.gov/cases/21675630-a711-4e98-bfe9-67e4bac3f4de

Female, 62.7 years: Serous carcinoma, NOS (ICD-O-3 8441/3) of the peritoneum; metastasis biopsied or resected from the colon. Tumor nuclei on the sequenced sample's slide: 20% (pathologist estimate recorded by GDC). Sample type: Metastatic.
